Gene-level copy-number profile of tumor specimen HTMCP-03-06-02174-01A from CGCI case HTMCP-03-06-02174, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA2; Tumor grade: G3.
Specimen HTMCP-03-06-02174-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bd64b3b0-8067-42fe-beca-0835f1625a32.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02174-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/408cfd1a-84b7-4024-804e-2b43e58cae87

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 31; copy number 2: 8,203; copy number 3: 736; copy number 4: 43,913; copy number 5: 2,780; copy number 6: 1,245; copy number 8: 52; copy number 10: 1,153; copy number 11: 254; copy number 12: 1.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–2): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr11:4,233,288–4,279,192, 3 genes: SSU72P5, SSU72P2, SSU72P6.
- chr13:57,314,739–57,315,909, 1 gene: SLC25A5P4.
- chr15:20,916,686–21,058,440, 11 genes (within-gene range 0–5): NF1P1, MIR5701-1, LINC01193, OR11J2P, OR11J5P, IGHD5OR15-5B, IGHD4OR15-4B, IGHD3OR15-3B, IGHD2OR15-2B, IGHD1OR15-1B, FAM30C.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,408 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:119,703,022–142,448,062, 463 genes, copy number 10–11 (broad region; genes not listed).
- chr3:142,580,910–192,767,764, 774 genes, copy number 10–12 (within-gene range 8–12) (broad region; genes not listed).
- chr3:192,796,815–198,123,232, 169 genes, copy number 10–11 (broad region; genes not listed).
- chr5:150,930,645–150,952,460, 2 genes, copy number 10: ZNF300P1, AC022106.1.

Autosomal genes at a single copy (total copy number 1): 31. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
